Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4JV, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4JV-01A (Primary Tumor).

DOB:
Physician

Sex: F

Accession

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) RIGHT THYROID LOBE AND ISTHMUS: PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Right lobe

Multi-focal: No

Size = 2.5 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Lymph nodes: No tumor present in 1 lymph nodes

(B) SUPERIOR RIGHT POLE NODE:

Thyroid tissue, no tumor present.

ICD-0-3

Path: carcinoma, papillary, end follicular 8340/3

Site: thyroid, NOS C73.9

hw
10/4/12

CCLF: carcinoma, papillary thyroid 8260/3

GROSS DESCRIPTION

(A) RIGHT THYROID LOBE AND ISTHMUS – Right thyroid (4.5 x 2.5 x 1.8 cm) and isthmus (1.5 x 1.0 x 0.8 cm). Serial sectioning revealed relatively well circumscribed nodule measuring 2.5 cm in greatest dimension and is confined to the thyroid. Representative sections of the nodule is sent for frozen in A1 and A2. The rest of the specimen is entirely submitted from superior to inferior in A3-A10.

*FS/DX: FOLLICULAR NEOPLASM, DEFER TO PERMANENT.

(B) SUPERIOR RIGHT POLE NODE – One piece of pink soft tissue (0.3 x 0.2 x 0.1 cm) and entirely submitted for frozen in B.

*FS/DX: THYROID TISSUE PRESENT.

CLINICAL HISTORY

None given.

SNOMED CODES

T-B6000, M-83403, T-C4200, M-00110,

"Some tests reported here may have been developed and performance characteristics determined by These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report

File under: Pathology

Source: NCI Genomic Data Commons file c8393646-64e8-45f4-a36e-61a3dbe5343d (TCGA-EL-A4JV.1131E38A-38F4-4187-85E4-AC1B3195C59F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).